Gene-level copy-number profile of tumor specimen C3L-02649-04 from CPTAC case C3L-02649, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 62.3 years (22,773 days).
Specimen C3L-02649-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67425da9-6c70-49e7-af2e-553f38923ba7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02649-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/71f07eca-595d-4f03-8cda-00fe063ba4b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 100; copy number 1: 3,771; copy number 2: 23,347; copy number 3: 13,988; copy number 4: 8,024; copy number 5: 3,985; copy number 6: 1,074; copy number 7: 3,231; copy number 8: 109; copy number 9: 3; copy number 10: 191; copy number 11: 471; copy number 12: 618.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,831,410, 3 genes: PRAMEF1, LINC01784, PRAMEF11.
- chr1:65,248,219–65,641,559, 8 genes (within-gene range 0–2): DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1.
- chr9:21,403,081–23,849,914, 39 genes: IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1.
- chr13:87,219,004–88,236,969, 14 genes: UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1, LINC00373, RPL29P29.
- chr17:18,450,244–18,551,705, 9 genes (within-gene range 0–2): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,682 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,278,606–116,742,609, 17 genes, copy number 6: U3, ATP1A1, ATP1A1-AS1, RNU6-817P, LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2, CD58, NAP1L4P1, MIR548AC, IGSF3, MIR320B1, LINC02868, GAPDHP64, NEFHP1.
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 5–12 (broad region; genes not listed).
- chr2:77,652,025–81,496,327, 34 genes, copy number 6: AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99.
- chr2:151,788,984–152,649,826, 13 genes, copy number 6: ARL5A, AC097448.1, AC068547.1, CACNB4, AC079790.1, STAM2, RPL30P2, Y_RNA, FMNL2, NUDCP1, AC012066.1, AC012443.1, AC012443.2.
- chr2:159,615,296–226,185,371, 1,045 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:146,571,477–198,123,232, 898 genes, copy number 11–12 (broad region; genes not listed).
- chr4:49,486,926–49,589,529, 12 genes, copy number 5: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:68,509,441–68,616,137, 4 genes, copy number 6: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr4:68,646,597–68,670,652, 1 gene, copy number 6: UGT2B15.
- chr5:7,239,781–40,067,200, 460 genes, copy number 7–11 (broad region; genes not listed).
- chr5:40,909,497–44,828,592, 70 genes, copy number 10 (broad region; genes not listed).
- chr6:105,919–8,102,559, 168 genes, copy number 5 (broad region; genes not listed).
- chr6:9,596,110–16,295,549, 113 genes, copy number 5 (broad region; genes not listed).
- chr6:17,224,243–17,611,715, 7 genes, copy number 5: AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, FAM8A1.
- chr6:24,356,903–25,701,783, 38 genes, copy number 5 (within-gene range 2–5): KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2, CMAHP, AL133268.4, AL133268.1, AL590084.3, AL590084.1, AL590084.2, KATNBL1P5, AL024509.2, AL024509.1, CARMIL1, Y_RNA, RNU6-987P, SCGN.
- chr6:25,962,802–69,389,506, 1,129 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr6:167,784,537–167,826,812, 4 genes, copy number 6: LINC01558, AL009178.2, AL009178.3, AFDN-DT.
- chr7:62,275,361–69,507,622, 213 genes, copy number 5–6 (broad region; genes not listed).
- chr8:39,451,045–39,522,852, 1 gene, copy number 5: ADAM3A.
- chr9:12,134–118,204, 10 genes, copy number 6: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4.
- chr10:43,900,874–46,131,358, 57 genes, copy number 6: LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, CXCL12, RPL9P21, AL356157.2, AL356157.1, TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7, RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1, AL358394.1, AL512324.3, AL512324.6, RNU6-1207P, CUBNP2, OR6D1P, OR13A1, ALOX5, AL731567.1, MARCHF8, ZFAND4, AGAP10P, FAM21FP, AL645998.1, WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P.
- chr11:68,052,859–89,900,449, 501 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:111,040,098–111,889,474, 33 genes, copy number 5: RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN, SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3, FDXACB1, C11orf1, RPL37AP8.
- chr13:18,467,172–21,348,721, 101 genes, copy number 7 (broad region; genes not listed).
- chr13:65,309,855–86,937,108, 183 genes, copy number 5 (broad region; genes not listed).
- chr13:88,494,789–114,337,626, 353 genes, copy number 5 (broad region; genes not listed).
- chr17:26,981,694–30,360,566, 186 genes, copy number 7 (broad region; genes not listed).
- chr17:81,878,425–83,240,804, 82 genes, copy number 5 (broad region; genes not listed).
- chr18:6,919,496–7,301,153, 9 genes, copy number 6–9: LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1.
- chr18:14,613,137–15,330,282, 24 genes, copy number 6: OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005901.2, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr19:14,433,053–14,475,354, 3 genes, copy number 6: PKN1, AC008569.2, PTGER1.
- chr19:18,557,762–18,569,387, 1 gene, copy number 5 (within-gene range 2–5): KXD1.
- chr19:18,568,506–18,919,387, 14 genes, copy number 5 (within-gene range 2–5): AC005253.2, UBA52, CRLF1, REX1BD, TMEM59L, RN7SL155P, KLHL26, CRTC1, COMP, UPF1, GDF1, CERS1, AC005197.1, COPE.
- chr19:43,192,702–43,269,530, 3 genes, copy number 5: PSG4, CEACAMP10, PSG9.
- chr20:23,798,092–24,318,086, 11 genes, copy number 8: AL591074.1, CST2, CST5, CSTP1, AL133466.1, GGTLC1, POM121L3P, LINC01721, AL110503.1, RNU1-23P, AL158090.1.
- chr20:48,821,688–49,096,960, 5 genes, copy number 5 (within-gene range 4–5): AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L.
- chr21:8,762,386–8,846,646, 3 genes, copy number 6 (within-gene range 6–9): CR381670.2, SNX18P10, MTCO1P1.
- chr22:15,282,557–50,801,309, 1,352 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
